Somatic mutation profile of tumor specimen TCGA-BJ-A45J-01A (aliquot TCGA-BJ-A45J-01A-11D-A23U-08) from TCGA case TCGA-BJ-A45J, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.7 years (14,510 days).
Specimen TCGA-BJ-A45J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d6d69af-4f79-4d33-99ea-9c9fa539daf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45J-10A (Blood Derived Normal), aliquot TCGA-BJ-A45J-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/366180e1-c9c5-4aa1-a77c-83490c9966e2

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAPN9 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55239953, COSV99680684; called by muse, mutect2
- EFTUD2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV68184914; called by muse, mutect2
- GLE1 | c.1544G>C p.R515T | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV59410812; called by muse, mutect2
- LPP | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV57115675; called by muse, mutect2
- ULBP1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.031); catalogued as COSV57665157; called by muse, mutect2
- MICAL2 | c.4742C>G p.S1581C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SPTA1 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, mutect2
- BTBD2 | c.1191C>T p.V397= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV55310734; called by muse, mutect2, varscan2
- CHRNA10 | c.927C>T p.V309= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV51707354; called by muse, mutect2
- CYP1A2 | c.258G>A p.L86= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV59661131; called by muse, mutect2
